Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UM, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UM-01A (Primary Tumor).

[page 1 of 2]
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

year old with left thyroid nodule status post FNA which was positive for malignant cells.

Specimens Submitted:

1: SP: Thyroid; total thyroidectomy

DIAGNOSIS:

1. SP: Thyroid; total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type
with tall cell features < 50% per TSS / W

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.3 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

ICD-O3

carcinoma, papillary, thyroid

8260/3

site: thyroid, NOS

C73.9

52.12
RD

[page 2 of 2]
Adenoma(s) (away from the carcinoma):
Not Identified
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Parathyroid Glands:
Identified
One intra-thyroid unremarkable parathyroid

Lymph Nodes:
Number of nodes examined:3
Three benign lymph nodes (0/3)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "total thyroid" and consists of a thyroid weighing 14 g. The right lobe measures 5 x 3.2 x 0.7 cm, the left lobe measures 3.6 x 2.4 x 1 cm and the isthmus measures 1.8 x 0.4 x 0.3 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.3 x 0.9 x 0.8 cm non-encapsulated partially cystic nodule with calcifications located in the mid left pole. Sections through the remaining tissue is unremarkable. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for microscopic examination. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:
RL - right lobe
LL - left lobe
IS - isthmus

Summary of Sections:

Part 1: SP: Thyroid; total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
4	LL	4
6	RL	6

Source: NCI Genomic Data Commons file cc054563-2fb0-4923-9583-fc0d02ff4870 (TCGA-DJ-A3UM.1C0C70EB-0C68-438E-BF0E-E2A24B7800BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).